Somatic mutation profile of tumor specimen 0D94V2 from CCDI case PBBICF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,958 days).
Specimen 0D94V2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96f82076-a85a-4e06-8af8-82ce88312e93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D94V3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f9c9008-4648-4cfb-bb57-71ab0422df69

The open-access MAF lists 20 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, 5'UTR 3, Intron 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD200R1 | c.677G>A p.S226N (on ENST00000471858 / NM_170780.3; = p.S249N on NM_138806.4) | Missense Mutation (SNP) | VAF 137/674 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV99866723; called by muse, mutect2, varscan2
- FASN | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 170/1109 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs779383660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPP5F | c.2678G>A p.G893D | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763469140; called by muse, varscan2
- SHISA6 | c.402C>G p.H134Q | Missense Mutation (SNP) | VAF 375/856 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.196); catalogued as rs967511750; called by muse, mutect2, varscan2
- TMEM101 | c.81del p.W29Gfs*45 | Frame Shift Del (DEL) | VAF 340/736 reads (46%) | catalogued as COSV52814237; called by mutect2, varscan2
- KRTAP2-1 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.062); called by muse, varscan2
- PCNX1 | c.3456dup p.G1153Wfs*3 | Frame Shift Ins (INS) | VAF 213/448 reads (48%) | called by mutect2, varscan2
- PHLDA3 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 273/677 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SETMAR | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 161/647 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC23 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 128/651 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.416); called by muse, varscan2
- DCHS2 | c.1845C>A p.I615= | Silent (SNP) | VAF 259/590 reads (44%) | called by muse, mutect2, varscan2
- FREM3 | c.2787C>T p.T929= | Silent (SNP) | VAF 240/541 reads (44%) | catalogued as rs1475051096; called by muse, mutect2, varscan2
- GPRIN1 | c.2103A>G p.K701= | Silent (SNP) | VAF 295/547 reads (54%) | called by muse, mutect2, varscan2
- POM121L2 | c.642G>A p.P214= | Silent (SNP) | VAF 39/349 reads (11%) | catalogued as rs1296598053; called by muse, mutect2, varscan2
- TBC1D12 | c.1395G>T p.L465= | Silent (SNP) | VAF 40/1058 reads (4%) | called by muse, mutect2
- ARSJ | c.-30C>T | 5'UTR (SNP) | VAF 84/400 reads (21%) | catalogued as rs769829614; called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99987084; called by muse, varscan2
- MYOF | c.-88C>G | 5'UTR (SNP) | VAF 6/65 reads (9%) | called by mutect2, varscan2
- TOGARAM2 | c.-54del | 5'UTR (DEL) | VAF 166/326 reads (51%) | called by mutect2, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, varscan2
